Gene-level copy-number profile of tumor specimen TCGA-D8-A1J9-01A from TCGA case TCGA-D8-A1J9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 49.0 years (17,879 days).
Specimen TCGA-D8-A1J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6570866d-4604-4a9d-a672-516cb1168f6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1J9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/040ed1a3-cea3-4309-9c8d-ce8562118cb1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,661; copy number 2: 9,314; copy number 3: 9,386; copy number 4: 28,443; copy number 5: 393; copy number 6: 9,067; copy number 7: 392; copy number 8: 616; copy number 9: 155; copy number 10: 65; copy number 11: 1; copy number 13: 14; copy number 14: 19; copy number 15: 39; copy number 18: 26; copy number 21: 142; copy number 23: 5; copy number 25: 13; copy number 27: 1; copy number 30: 3; copy number 31: 6; copy number 46: 40; copy number 50: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1J9-01A-11D-A13J-01): tumor purity 0.69, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 533 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:24,069,731–24,088,051, 1 gene, copy number 30 (within-gene range 30–33): AL513317.1.
- chr9:32,886,601–33,025,130, 1 gene, copy number 23 (within-gene range 2–27): APTX.
- chr9:32,945,996–32,980,403, 2 genes, copy number 23–27: ASS1P12, TCEA1P4.
- chr9:33,025,273–36,022,113, 162 genes, copy number 13–21 (within-gene range 2–21) (broad region; genes not listed).
- chr9:88,534,033–92,620,529, 76 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr9:114,850,968–115,402,644, 1 gene, copy number 9 (within-gene range 6–9): DELEC1.
- chr9:115,119,539–120,245,050, 36 genes, copy number 9–18 (within-gene range 6–18): AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1, LINC01613, AL441989.1, MIR147A.
- chr9:120,952,335–123,380,324, 62 genes, copy number 10 (broad region; genes not listed).
- chr9:123,402,525–123,493,156, 3 genes, copy number 10: MIR601, MIR7150, AL445489.1.
- chr9:126,516,417–128,446,628, 75 genes, copy number 9 (broad region; genes not listed).
- chr9:128,468,957–128,473,012, 1 gene, copy number 9: ODF2-AS1.
- chr17:32,830,219–32,997,877, 5 genes, copy number 13 (within-gene range 6–13): Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:33,827,699–34,156,000, 6 genes, copy number 31 (within-gene range 2–31): AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1.
- chr17:34,479,272–34,859,046, 6 genes, copy number 30–50: AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:36,601,583–37,884,743, 32 genes, copy number 11–15: MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7.
- chr17:38,996,323–40,195,656, 56 genes, copy number 23–46: AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867.
- chr20:9,068,763–9,481,242, 1 gene, copy number 15 (within-gene range 8–15): PLCB4.
- chr20:22,547,671–22,886,068, 7 genes, copy number 15: LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4.

Autosomal genes at a single copy (total copy number 1): 1,661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
